Somatic mutation profile of tumor specimen BA2653D (aliquot aq-BA2653D) from BEATAML1.0 case 2191, project BEATAML1.0-COHORT (Functional Genomic Landscape of Acute Myeloid Leukemia). Sex at birth: female; Vital status: Dead; Primary diagnosis: Acute myeloid leukemia with mutated CEBPA; Tissue or organ of origin: Bone marrow; Age at diagnosis: 42.8 years (15,616 days).
Specimen BA2653D: Sample type: Primary Blood Derived Cancer - Peripheral Blood; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Peripheral Blood NOS; Preservation method: Snap Frozen.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) e61b1b60-9dee-4c2b-96d0-85ac704ded17.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen BA2468D (Solid Tissue Normal), aliquot aq-BA2468D; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/1791a958-773f-4ad1-92cc-3bbefeb36ad8

The open-access MAF lists 11 somatic variants for this specimen: 9 protein-altering or splice-affecting, 1 silent, 1 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 9, Silent 1, 5'Flank 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- CC2D1B | c.448G>A p.V150I | Missense Mutation (SNP) | VAF 14/93 reads (15%) | SIFT tolerated (0.42); PolyPhen benign (0.003); catalogued as rs758431439, COSV52561965; called by muse, mutect2, varscan2
- CCNG2 | c.875C>T p.T292M | Missense Mutation (SNP) | VAF 28/73 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs533819533; called by muse, mutect2, varscan2
- DAB1 | c.1385G>A p.R462H (on ENST00000371231; = p.R429H on NM_021080.5 and 5 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 18/88 reads (20%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.869); catalogued as rs144347021, COSV64692596; called by muse, varscan2
- RPGRIP1 | c.2924T>C p.I975T | Missense Mutation (SNP) | VAF 10/62 reads (16%) | SIFT tolerated (0.49); PolyPhen benign (0); catalogued as rs886050399; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- BLM | c.442T>A p.L148I | Missense Mutation (SNP) | VAF 45/287 reads (16%) | SIFT tolerated (0.57); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- EMB | c.79G>A p.A27T | Missense Mutation (SNP) | VAF 12/64 reads (19%) | SIFT tolerated, low confidence (0.9); PolyPhen benign (0.001); called by muse, mutect2
- GABRG3 | c.1189T>C p.W397R | Missense Mutation (SNP) | VAF 20/132 reads (15%) | SIFT tolerated (0.26); PolyPhen possibly damaging (0.722); called by muse, mutect2, varscan2
- RGS22 | c.2549A>G p.H850R | Missense Mutation (SNP) | VAF 37/216 reads (17%) | SIFT tolerated (0.1); PolyPhen benign (0.079); called by muse, mutect2, varscan2
- RPRD1B | c.406C>A p.P136T | Missense Mutation (SNP) | VAF 18/69 reads (26%) | SIFT tolerated (0.33); PolyPhen benign (0.01); called by muse, mutect2, varscan2
- LAMB1 | c.1035C>T p.H345= | Silent (SNP) | VAF 11/70 reads (16%) | called by muse, mutect2, varscan2
- AC092865.4 | chr12:8390653 G>T | 5'Flank (SNP) | VAF 8/24 reads (33%) | catalogued as rs190105354; called by muse, varscan2
